PECGS case C083-000011 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/de7d52ac-9b6a-4545-bb5a-4dc6dd13dd07

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 53 years; Year of birth: 1965; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 53.4 years (19,504 days); AJCC clinical stage: Stage IIIC; Progression or recurrence: no.

Other clinical attributes
- BMI: 29.95.

Exposures
- Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000011_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000011_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
